Somatic mutation profile of tumor specimen TCGA-86-8359-01A (aliquot TCGA-86-8359-01A-11D-2323-08) from TCGA case TCGA-86-8359, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 52.3 years (19,088 days).
Specimen TCGA-86-8359-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 856aea07-54b1-4154-9036-4bcd5cc753a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8359-10A (Blood Derived Normal), aliquot TCGA-86-8359-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d79e33f3-cf31-4798-9278-4571536ec4c2

The open-access MAF lists 182 somatic variants for this specimen: 133 protein-altering or splice-affecting, 42 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 42, Frame Shift Del 6, Splice Site 5, Nonsense Mutation 5, Intron 5, Frame Shift Ins 3, RNA 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 4/13 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS19 | c.3175G>T p.G1059C | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99176293; called by muse, mutect2, varscan2
- AK9 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1298783616, COSV99572317; called by muse, mutect2
- AL031681.2 | c.3101A>T p.H1034L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.283); catalogued as COSV100916885; called by muse, mutect2, varscan2
- ANK2 | c.843G>T p.M281I | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99999499; called by muse, mutect2
- ANKEF1 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV101000977; called by muse, mutect2
- APCS | c.200G>T p.S67I | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99661181; called by muse, mutect2, varscan2
- ARHGAP24 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV101232939; called by muse, mutect2, varscan2
- ATP13A3 | c.1559+1G>T p.X520_splice | Splice Site (SNP) | VAF 26/101 reads (26%) | catalogued as COSV55464616, COSV99756163; called by muse, mutect2, varscan2
- BRINP3 | c.2067C>A p.Y689* | Nonsense Mutation (SNP) | VAF 19/117 reads (16%) | catalogued as COSV100818281; called by muse, mutect2, varscan2
- C11orf42 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.663); catalogued as rs777415343, COSV99791686; called by muse, mutect2, varscan2
- CABS1 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 21/102 reads (21%) | catalogued as COSV56733530, COSV99908927; called by muse, mutect2, varscan2
- CACNB2 | c.1861T>A p.C621S (on ENST00000324631 / NM_201596.3; = p.C566S on NM_000724.4) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.055); catalogued as COSV99992911; called by muse, mutect2, varscan2
- CCDC66 | c.2670C>G p.D890E (on ENST00000394672 / NM_001353147.1; = p.D856E on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV100413638; called by muse, mutect2, varscan2
- CDH18 | c.910A>T p.T304S | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.062); catalogued as COSV99931904; called by muse, mutect2, varscan2
- CFB | c.1037-1G>C p.X346_splice | Splice Site (SNP) | VAF 19/87 reads (22%) | catalogued as COSV100190596; called by muse, mutect2, varscan2
- CLASP1 | c.3115G>C p.V1039L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV99752812; called by muse, mutect2, varscan2
- CLCN1 | c.2630G>T p.G877V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100577689; called by muse, mutect2, varscan2
- COL11A1 | c.1753G>A p.D585N | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100614949; called by muse, mutect2, varscan2
- COL8A2 | c.88G>T p.G30C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV100290924; called by muse, mutect2, varscan2
- CSMD2 | c.4361G>T p.G1454V | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99585659; called by muse, mutect2, varscan2
- DENND1A | c.1930G>T p.D644Y | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101011752; called by muse, mutect2, varscan2
- DENND2C | c.932A>G p.E311G | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101283884; called by muse, mutect2
- DLGAP3 | c.937C>A p.L313I | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.23); catalogued as COSV99332123; called by muse, mutect2, varscan2
- DMRTA1 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV100364639; called by muse, mutect2
- DNAJC12 | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 47/144 reads (33%) | catalogued as COSV99830447; called by muse, mutect2, varscan2
- DOCK2 | c.1822T>C p.S608P | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99910150; called by muse, mutect2, varscan2
- DSCAM | c.709A>T p.M237L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.246); catalogued as COSV101259004; called by muse, mutect2, varscan2
- DYNC1I1 | c.524C>A p.A175D | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100267572; called by muse, mutect2
- EDIL3 | c.368G>T p.C123F | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as COSV99674410; called by muse, varscan2
- EMC2 | c.180G>T p.M60I | Missense Mutation (SNP) | VAF 92/185 reads (50%) | SIFT tolerated (0.93); PolyPhen benign (0.045); catalogued as COSV99623852; called by muse, mutect2, varscan2
- ENAM | c.3106C>A p.Q1036K | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs774117576, COSV101252912; called by muse, mutect2, varscan2
- EPHA5 | c.2699C>G p.P900R | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99895916; called by muse, mutect2, varscan2
- EPHB6 | c.2788G>C p.G930R | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.781); catalogued as COSV100844110; called by muse, mutect2, varscan2
- FAM135B | c.3861T>G p.D1287E | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99418477; called by muse, mutect2, varscan2
- FAM135B | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 131/275 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV52719715, COSV99417311; called by muse, varscan2
- FBN2 | c.2221T>A p.C741S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99324747; called by muse, mutect2, varscan2
- FERD3L | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51763167, COSV99284669; called by muse, mutect2
- FMNL3 | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53302493; called by muse, mutect2, varscan2
- FRMPD4 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV101042080; called by muse, mutect2, varscan2
- GABRA1 | c.1318G>T p.A440S | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.855); catalogued as COSV99195693; called by muse, mutect2, varscan2
- GALNT14 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100204037; called by muse, mutect2, varscan2
- GALNT17 | c.150C>A p.N50K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.095); catalogued as COSV100352203; called by muse, mutect2, varscan2
- GIMAP4 | c.288T>A p.N96K | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV99750403; called by muse, mutect2, varscan2
- GPATCH2 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV100861496; called by muse, mutect2
- GRHL3 | c.1049T>A p.V350E (on ENST00000350501 / NM_198174.3; = p.V355E on NM_021180.3) | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV99359002; called by muse, mutect2, varscan2
- GSTA5 | c.460A>T p.S154C | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99489373; called by muse, mutect2, varscan2
- HCRTR2 | c.281T>C p.V94A | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100904120; called by muse, mutect2, varscan2
- HECW1 | c.3458G>A p.R1153Q | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs201521619, COSV67837133; called by muse, mutect2, varscan2
- HERC2 | c.4519G>T p.A1507S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.976); catalogued as COSV55315251, COSV99870702; called by muse, mutect2, varscan2
- HSPBP1 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs200454662, COSV99728911; called by muse, mutect2, varscan2
- IGSF10 | c.6875T>A p.V2292D | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99176595; called by muse, mutect2, varscan2
- KLHL4 | c.374A>G p.Q125R | Missense Mutation (SNP) | VAF 61/95 reads (64%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100909077; called by muse, mutect2, varscan2
- KLK9 | c.708C>G p.S236R | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV99143874; called by muse, mutect2
- LCE1B | c.23A>T p.Q8L | Missense Mutation (SNP) | VAF 86/228 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.425); catalogued as COSV100780251; called by muse, mutect2, varscan2
- LDOC1 | c.30C>A p.H10Q | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100983128, COSV65159143; called by muse, mutect2, varscan2
- LRP1 | c.5784C>A p.D1928E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99674312; called by muse, mutect2, varscan2
- LRP1B | c.9751C>A p.L3251M | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV101251922; called by muse, mutect2, varscan2
- LRRC17 | c.917T>G p.F306C | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.732); catalogued as COSV99978194; called by muse, mutect2, varscan2
- LRTOMT | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV99194374; called by muse, mutect2
- MAGT1 | c.559G>A p.A187T (on ENST00000618282 / NM_001367916.1; = p.A219T on NM_032121.5) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.088); catalogued as COSV100800013, COSV63782877; called by muse, mutect2, varscan2
- MORC1 | c.1303G>T p.V435F | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV99224984, COSV99225105; called by muse, mutect2, varscan2
- MTERF1 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 80/158 reads (51%) | catalogued as rs368433062; called by muse, mutect2, varscan2
- MUC16 | c.33380C>T p.P11127L | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.105); catalogued as COSV101198049; called by muse, mutect2, varscan2
- MYH11 | c.5552T>A p.L1851Q | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100257628; called by muse, mutect2, varscan2
- NCOA5 | c.1457G>A p.S486N | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99275149; called by muse, mutect2, varscan2
- NDST4 | c.218C>A p.T73K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as COSV99995360, COSV99997632; called by muse, mutect2, varscan2
- NFASC | c.143C>A p.A48E (on ENST00000339876 / NM_001378329.1; = p.A42E on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV100362752, COSV58363732; called by muse, mutect2, varscan2
- NLRP7 | c.1248C>A p.S416R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV100051583; called by muse, mutect2, varscan2
- NLRP7 | c.659C>A p.P220H | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100051584; called by muse, mutect2, varscan2
- NOX3 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1035239474, COSV99342673; called by muse, mutect2, varscan2
- NPAP1 | c.271G>C p.G91R | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.369); catalogued as COSV100274742, COSV61509122; called by muse, mutect2, varscan2
- NPR3 | c.1184G>T p.R395I | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV54093139, COSV99422180; called by muse, mutect2, varscan2
- NR5A2 | c.1305_1306insC p.A436Rfs*9 (on ENST00000367362 / NM_205860.3; = p.A390Rfs*9 on NM_003822.5) | Frame Shift Ins (INS) | VAF 11/100 reads (11%) | catalogued as COSV99370615; called by mutect2, pindel, varscan2
- OR10G2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1176332906, COSV101606931; called by muse, mutect2, varscan2
- OR11H1 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99421547; called by mutect2, varscan2
- OR14A16 | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.506); catalogued as COSV100713687, COSV62926304, COSV62927619; called by muse, mutect2, varscan2
- OR1M1 | c.245T>A p.L82Q | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101447578, COSV70037650; called by muse, mutect2, varscan2
- OR2M4 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.049); catalogued as COSV100140963, COSV100141105, COSV60709407; called by muse, mutect2
- OR51A7 | c.931G>T p.G311W | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.293); catalogued as COSV63788256; called by muse, mutect2, varscan2
- OR5H14 | c.85C>A p.L29M | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV71193495; called by muse, mutect2, varscan2
- OVCH1 | c.2859C>A p.S953R | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as COSV100548219; called by muse, mutect2, varscan2
- PABPC4 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100865406; called by muse, mutect2, varscan2
- PAEP | c.200C>A p.T67N | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99478840; called by muse, mutect2, varscan2
- PLA2R1 | c.647G>T p.W216L | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99322086; called by muse, mutect2, varscan2
- PLRG1 | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100122966; called by muse, mutect2
- PNPLA6 | c.3947A>G p.E1316G (on ENST00000414982 / NM_001166111.2; = p.E1268G on NM_006702.5) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs141102875, COSV99653070; called by muse, mutect2, varscan2
- PRPF19 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as COSV99920438; called by muse, mutect2, varscan2
- PRPF8 | c.5532G>T p.E1844D | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100517109; called by muse, mutect2, varscan2
- PRUNE2 | c.1013C>A p.P338H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100944196; called by muse, mutect2, varscan2
- PSG6 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 141/525 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99413504; called by muse, mutect2, varscan2
- PXDNL | c.3781G>A p.G1261S | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.646); catalogued as COSV62479293; called by muse, mutect2, varscan2
- ROR2 | c.1927G>C p.A643P | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs771184180, COSV100995452, COSV65216909; called by muse, mutect2, varscan2
- RTL4 | c.847T>C p.C283R | Missense Mutation (SNP) | VAF 53/78 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100465708; called by muse, mutect2, varscan2
- SACS | c.9459G>T p.L3153F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1368110748, COSV101207164; called by muse, mutect2, varscan2
- SAGE1 | c.2354C>G p.A785G | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as COSV100186598, COSV61011517; called by muse, mutect2, varscan2
- SDCCAG8 | c.1361G>T p.C454F | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100653787; called by muse, mutect2, varscan2
- SH3TC2 | c.2834T>A p.M945K | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV100101149; called by muse, mutect2, varscan2
- SLC16A7 | c.44A>T p.D15V | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99676089; called by muse, mutect2, varscan2
- SLC18A1 | c.489-2A>T p.X163_splice | Splice Site (SNP) | VAF 7/29 reads (24%) | catalogued as rs1475939684, COSV52351340, COSV99368275; called by muse, mutect2, varscan2
- SLC19A1 | c.1181A>T p.E394V | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202114789, COSV100229091; called by muse, mutect2, varscan2
- SLITRK3 | c.2698G>T p.V900L | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); catalogued as COSV99578454; called by muse, mutect2, varscan2
- SNTG1 | c.668C>A p.T223K | Missense Mutation (SNP) | VAF 61/372 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV99381054; called by muse, mutect2, varscan2
- SORCS1 | c.2876C>G p.A959G | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV53875623, COSV99543000; called by muse, mutect2, varscan2
- SPTBN1 | c.5044G>A p.G1682S | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.695); catalogued as COSV100441727; called by muse, mutect2
- STK11 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV58821580, COSV58822105; called by muse, mutect2, varscan2
- SYT13 | c.960G>T p.K320N | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.426); catalogued as COSV99194637; called by muse, mutect2, varscan2
- TAL1 | c.926C>A p.A309E | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV53749056, COSV99595866; called by muse, mutect2, varscan2
- TRRAP | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62857021; called by muse, mutect2, varscan2
- UBAP1 | c.1499G>A p.G500E | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs537789793, COSV99902818; called by muse, mutect2, varscan2
- UBR1 | c.704A>T p.H235L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.987); catalogued as COSV99316593; called by muse, mutect2, varscan2
- UGT1A3 | c.720G>C p.Q240H | Missense Mutation (SNP) | VAF 134/323 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.858); catalogued as COSV100529446, COSV100530334; called by muse, mutect2, varscan2
- USH2A | c.2477G>T p.C826F | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100228557; called by muse, mutect2, varscan2
- USP14 | c.1367G>A p.S456N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.584); catalogued as rs994074508, COSV99863223; called by muse, mutect2, varscan2
- USP32 | c.1841A>T p.Q614L | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.024); catalogued as COSV100341374; called by muse, mutect2, varscan2
- VIPR1 | c.790G>T p.G264W | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100285480; called by muse, mutect2, varscan2
- ZNF184 | c.161G>T p.R54M | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99279368; called by muse, mutect2, varscan2
- ZNF304 | c.878A>T p.H293L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99988371; called by muse, mutect2, varscan2
- ZNF345 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.258); catalogued as COSV100080142; called by muse, mutect2, varscan2
- ZNF677 | c.809A>T p.K270M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100447766; called by muse, mutect2, varscan2
- CCDC150 | c.2039_2048del p.N680Tfs*24 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- CEP350 | c.8919+3_8919+6del p.X2973_splice | Splice Site (DEL) | VAF 6/32 reads (19%) | called by pindel, varscan2
- CMSS1 | c.323dup p.L108Ffs*4 | Frame Shift Ins (INS) | VAF 34/100 reads (34%) | called by mutect2, pindel, varscan2
- CRY1 | c.158+2del p.X53_splice | Splice Site (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel, varscan2
- GDF10 | c.964C>A p.Q322K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HIF3A | c.4_18del p.ALGLQ2_?6 | Translation Start Site (DEL) | VAF 10/90 reads (11%) | called by mutect2, pindel
- IKZF2 | c.717_718dup p.P240Lfs*28 | Frame Shift Ins (INS) | VAF 23/72 reads (32%) | called by mutect2, pindel, varscan2
- KIAA2026 | c.1613_1614del p.E538Afs*4 | Frame Shift Del (DEL) | VAF 11/98 reads (11%) | called by pindel, varscan2
- KRTAP10-7 | c.232C>A p.Q78K | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SND1 | c.622del p.V208Sfs*82 | Frame Shift Del (DEL) | VAF 20/105 reads (19%) | called by mutect2, pindel, varscan2
- TRIP11 | c.62del p.G21Afs*18 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- TUT4 | c.2723del p.G908Afs*6 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel, varscan2
- ZWINT | c.595del p.A199Qfs*76 | Frame Shift Del (DEL) | VAF 26/132 reads (20%) | called by mutect2, pindel, varscan2
- ADGRL2 | c.2112C>G p.V704= (on ENST00000370717 / NM_001366005.1; = p.V691= on NM_012302.4) | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs764194054, COSV99586978; called by muse, mutect2, varscan2
- AL592490.1 | c.291G>T p.G97= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV69426654; called by muse, mutect2
- BANK1 | c.693A>C p.T231= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV100535815; called by muse, mutect2, varscan2
- BRINP3 | c.528G>A p.T176= | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as rs141418514; called by muse, mutect2, varscan2
- C6orf118 | c.165C>T p.D55= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as rs760006970, COSV57815514, COSV57815652; called by muse, mutect2, varscan2
- CDHR2 | c.294C>T p.S98= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs780760064, COSV99990980; called by muse, mutect2, varscan2
- COL5A1 | c.5196G>T p.R1732= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100879442; called by mutect2, varscan2
- COL7A1 | c.1278G>T p.L426= | Silent (SNP) | VAF 27/156 reads (17%) | catalogued as COSV100094970; called by muse, mutect2, varscan2
- CPED1 | c.2355T>C p.Y785= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as rs777591616, COSV100119920; called by muse, mutect2, varscan2
- CTBP1 | c.177G>T p.T59= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV99337425, COSV99337663; called by muse, mutect2, varscan2
- CYP2C19 | c.1179T>A p.S393= | Silent (SNP) | VAF 22/139 reads (16%) | catalogued as COSV100990225; called by muse, mutect2, varscan2
- DMRTA1 | c.282G>A p.T94= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100364636; called by muse, mutect2
- DNAH11 | c.10299G>T p.V3433= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV100176881; called by muse, mutect2, varscan2
- DOK7 | c.1164C>T p.C388= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs763619811, COSV100403124; called by muse, varscan2
- EDIL3 | c.369C>T p.C123= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as rs761164390, COSV99674405, COSV99675326; called by muse, varscan2
- FCGBP | c.6597G>A p.V2199= | Silent (SNP) | VAF 28/454 reads (6%) | called by muse, mutect2
- FKBP11 | c.249G>A p.L83= | Silent (SNP) | VAF 83/134 reads (62%) | catalogued as COSV99872668; called by muse, mutect2, varscan2
- FOXB2 | c.786C>T p.S262= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV65023206; called by muse, mutect2, varscan2
- GFAP | c.990G>T p.R330= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV53652410, COSV99493021; called by muse, mutect2, varscan2
- HCN1 | c.258G>T p.G86= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100298379; called by muse, mutect2, varscan2
- KCNQ3 | c.2472G>T p.S824= | Silent (SNP) | VAF 44/92 reads (48%) | catalogued as COSV66473419, COSV66484458; called by muse, mutect2, varscan2
- KCNT2 | c.3264T>A p.S1088= | Silent (SNP) | VAF 78/305 reads (26%) | catalogued as COSV99651330; called by muse, mutect2, varscan2
- KCNU1 | c.2577C>T p.V859= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as COSV67758837; called by muse, mutect2, varscan2
- KIF3A | c.1009C>A p.R337= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV101109213, COSV66413083; called by muse, mutect2, varscan2
- MXI1 | c.99C>A p.P33= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100221677; called by muse, mutect2
- NCKAP5 | c.3174A>G p.Q1058= | Silent (SNP) | VAF 78/160 reads (49%) | catalogued as COSV100489905; called by muse, mutect2, varscan2
- NLRC3 | c.682C>T p.L228= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100072400; called by muse, mutect2, varscan2
- PDCD1LG2 | c.501C>A p.S167= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV101173065; called by muse, mutect2, varscan2
- PIM2 | c.33G>T p.A11= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV50238322, COSV99331561; called by muse, mutect2, varscan2
- PTH1R | c.1236G>T p.V412= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100480784; called by muse, mutect2, varscan2
- RAPGEF2 | c.1290G>T p.G430= | Silent (SNP) | VAF 43/115 reads (37%) | catalogued as COSV100030474; called by muse, mutect2, varscan2
- RBSN | c.2019A>T p.A673= | Silent (SNP) | VAF 24/194 reads (12%) | catalogued as COSV99514976; called by muse, mutect2, varscan2
- SALL3 | c.2106G>C p.T702= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV101609929; called by muse, mutect2, varscan2
- SLC8A2 | c.2140C>A p.R714= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as COSV99369627; called by muse, varscan2
- SMCHD1 | c.804T>G p.S268= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99860487; called by muse, mutect2
- SMOC1 | c.1245C>A p.V415= | Silent (SNP) | VAF 59/281 reads (21%) | catalogued as COSV100734274; called by muse, mutect2, varscan2
- TMPRSS11B | c.714C>G p.V238= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100219222; called by muse, mutect2, varscan2
- TRIO | c.6378A>G p.S2126= | Silent (SNP) | VAF 41/251 reads (16%) | catalogued as COSV100709793; called by muse, mutect2, varscan2
- TSHZ3 | c.3147C>A p.T1049= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV53670599; called by muse, mutect2, varscan2
- UHRF2 | c.2001A>G p.S667= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99436112; called by muse, mutect2
- ZFYVE26 | c.1149C>T p.A383= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV100720051; called by muse, mutect2, varscan2
- ZNF114 | c.165C>T p.D55= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as rs150295509, COSV100251898; called by muse, mutect2, varscan2
- CIRBP | c.-7+610G>T | Intron (SNP) | VAF 20/37 reads (54%) | catalogued as COSV100309680; called by muse, mutect2, varscan2
- EFCAB2 | c.781+3588A>G | Intron (SNP) | VAF 5/71 reads (7%) | catalogued as COSV100833789; called by muse, mutect2
- PRMT5 | c.110+29G>A | Intron (SNP) | VAF 19/127 reads (15%) | catalogued as rs376981525, COSV99362744; called by muse, mutect2, varscan2
- SNORD116-13 | n.64G>T | RNA (SNP) | VAF 36/113 reads (32%) | called by muse, mutect2, varscan2
- SV2C | c.581-20938C>A | Intron (SNP) | VAF 43/180 reads (24%) | catalogued as COSV59218358; called by muse, mutect2, varscan2
- TP73-AS1 | n.1561C>T | RNA (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23354G>A | Intron (SNP) | VAF 31/239 reads (13%) | catalogued as rs555741522, COSV59386222; called by muse, mutect2, varscan2
